Surgical pathology report (de-identified scan), TCGA case TCGA-DX-A7EM, project TCGA-SARC (Sarcoma), tissue source site Memorial Sloan Kettering, specimen TCGA-DX-A7EM-01A (Primary Tumor).

[page 1 of 2]
SURGICAL PATHOLOGY REPORT

* Addendum *

[REDACTED]

....

Clinical Diagnosis & History:

[REDACTED] with left retroperitoneal leiomyosarcoma.

Specimens Submitted:

1: RETROPERITONEUM, LEFT; RESECTION

DIAGNOSIS:

1. LEFT RETROPERITONEUM; RESECTION:
- HIGH GRADE LEIOMYOSARCOMA, WITH FOCAL AREAS OF NECROSIS.
- TUMOR SIZE: 4 x 3.1 x 2.8 CM.
- TUMOR EXTENDS UP TO 0.1 CM FROM THE INKED MARGIN OF RESECTION.

I ATTEST THAT THE ABOVE DIAGNOSIS IS BASED UPON MY PERSONAL EXAMINATION OF THE SLIDES (AND/OR OTHER MATERIAL), AND THAT I HAVE REVIEWED AND APPROVED THIS REPORT.

*** Report Electronically Signed Out ***

Gross Description:

1) The specimen is received fresh labeled "left retroperitoneal leiomyosarcoma, radical resection" and consists of a portion of unoriented fatty tissue measuring 11 x 10.5 x 4.5 cm. A firm white irregularly shaped mass with a thin translucent membranous capsule is present within the fatty tissue abutting the peripheral margin and measuring 4 x 3.1 x 2.8 cm. The surface of the mass is inked black and sectioning reveals a bulging whirled white tan cut surface. Representative sections and tps are submitted.

Summary of sections:

T - tumor
F - adjacent fat

** Continued on next page **

ICD-O-3

Leiomyosarcoma NOS
8890/3

Retroperitoneum
C480

9/26/13

[page 2 of 2]
SURGICAL PATHOLOGY REPORT

Summary of Sections:

Part 1: RETROPERITONEUM, LEFT; RESECTION

Block	Sect.	Site	PCs
2		F	2
5		T	5

Procedures/Addenda:

Addendum

Status: Signed Out
By:

Addendum Diagnosis

- LEFT RETROPERITONEUM; RESECTION:
- A MITOTIC COUNT WAS PERFORMED SHOWING UP TO 11 MITOTIC FIGURES PER 10 HIGH POWER FIELDS (40X), IN KEEPING WITH A HIGH GRADE LEIOMYOSARCOMA.

** End of Report **

Source: NCI Genomic Data Commons file cbd0beed-450f-4f31-9164-2fe1e8e83dca (TCGA-DX-A7EM.AF205AEA-E9B9-47DD-B8AF-1EA25CD30135.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).